Somatic mutation profile of tumor specimen TCGA-L5-A4OT-01A (aliquot TCGA-L5-A4OT-01A-11D-A28B-09) from TCGA case TCGA-L5-A4OT, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 77.1 years (28,162 days).
Specimen TCGA-L5-A4OT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d181b84-9ca3-4466-b656-f2847f17c02f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A4OT-11A (Solid Tissue Normal), aliquot TCGA-L5-A4OT-11A-11D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0b0e755-1009-4b21-9dc9-83e2ac0f0483

The open-access MAF lists 234 somatic variants for this specimen: 180 protein-altering or splice-affecting, 47 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 165, Silent 47, Nonsense Mutation 10, RNA 4, Splice Site 2, Frame Shift Ins 2, Intron 2, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOL4 | c.1267T>A p.L423M | Missense Mutation (SNP) | VAF 28/50 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52337695, COSV52338459, COSV52349574; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 29/59 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2744A>C p.K915T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.98); catalogued as rs1234949048, COSV55945450, COSV55964424; called by muse, mutect2, varscan2
- ACCSL | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as rs779808371, COSV66580893; called by muse, mutect2, varscan2
- ADCY2 | c.1802A>C p.K601T | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as rs529971476; called by muse, mutect2, varscan2
- AOC2 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 5/61 reads (8%) | catalogued as COSV53198275; called by muse, mutect2
- ASB1 | c.989A>C p.K330T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV52827423, COSV52827754; called by muse, mutect2, varscan2
- C1QTNF7 | c.732A>C p.E244D | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54856290; called by muse, mutect2, varscan2
- CACNA1A | c.5938C>A p.Q1980K | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.234); catalogued as COSV64207644; called by muse, mutect2
- CACNA2D3 | c.2987A>C p.K996T | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs749815729; called by muse, mutect2, varscan2
- CCDC61 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs373065477; called by muse, mutect2, varscan2
- CFHR4 | c.1367A>C p.K456T (on ENST00000367416 / NM_001201551.2; = p.K210T on NM_006684.5) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.082); catalogued as COSV52226389; called by muse, mutect2, varscan2
- CLIC4 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs752325844, COSV65526622; called by muse, mutect2, varscan2
- COL14A1 | c.1869A>C p.E623D | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV52852637; called by muse, mutect2, varscan2
- CPO | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1208465281, COSV99786634; called by muse, mutect2, varscan2
- CRB1 | c.3064A>C p.S1022R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); catalogued as COSV66328752; called by muse, mutect2, varscan2
- CTR9 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.133); catalogued as rs772135027, COSV63729465; called by muse, mutect2, varscan2
- CUBN | c.6134A>C p.N2045T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.124); catalogued as COSV100913796; called by muse, mutect2
- CYP2W1 | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as rs894293547; called by muse, mutect2, varscan2
- DCDC1 | c.3900A>C p.E1300D (on ENST00000597505 / NM_001367979.1; = p.E407D on NM_020869.3) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV58002128; called by muse, mutect2, varscan2
- DNAH5 | c.9633A>C p.K3211N | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.091); catalogued as COSV54213611; called by muse, mutect2, varscan2
- DOCK3 | c.1655A>C p.E552A | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99808613; called by muse, mutect2, varscan2
- EPAS1 | c.2375G>A p.G792E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99763054; called by muse, mutect2, varscan2
- EPHB1 | c.2144A>G p.Q715R | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as rs775383394, COSV101212595, COSV67673862; called by muse, mutect2, varscan2
- FAT4 | c.5092C>T p.R1698W | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755643759, COSV67882388; called by muse, mutect2, varscan2
- FAT4 | c.8657T>G p.L2886R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58674921, COSV58711887; called by muse, mutect2, varscan2
- FLG2 | c.4852G>A p.G1618R | Missense Mutation (SNP) | VAF 188/281 reads (67%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs774027082, COSV66170648; called by muse, mutect2, varscan2
- FLG2 | c.140A>C p.N47T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101166348; called by muse, mutect2, varscan2
- FSHR | c.582A>T p.Q194H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV58637145; called by muse, mutect2, varscan2
- GNAS | c.261A>C p.E87D | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.222); catalogued as COSV58344557; called by muse, mutect2, varscan2
- IL6ST | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV61140578; called by muse, mutect2, varscan2
- IRF4 | c.1123G>A p.G375S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs1169247876, COSV66704779; called by muse, mutect2, varscan2
- IRX6 | c.1123A>C p.S375R | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV51859427; called by muse, mutect2, varscan2
- IVL | c.998T>A p.L333Q | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV100908160; called by muse, mutect2, varscan2
- JAKMIP1 | c.743T>G p.V248G | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV51542710; called by muse, mutect2, varscan2
- KASH5 | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as rs762241865, COSV71358094; called by muse, mutect2, varscan2
- KCNH1 | c.1483T>C p.F495L (on ENST00000271751 / NM_172362.3; = p.F468L on NM_002238.4) | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV55068201; called by muse, mutect2, varscan2
- KCNMA1 | c.2023T>G p.F675V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV99699506; called by muse, mutect2, varscan2
- KCNT1 | c.1043G>A p.R348H (on ENST00000488444; = p.R367H on NM_020822.3) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as rs1400096269, COSV53711523; called by muse, mutect2, varscan2
- KSR2 | c.1454A>C p.K485T | Missense Mutation (SNP) | VAF 75/111 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV100194292; called by muse, mutect2, varscan2
- L3MBTL4 | c.1007A>C p.K336T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.115); catalogued as COSV53118685; called by muse, mutect2, varscan2
- LRP12 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.971); catalogued as COSV52632358; called by muse, mutect2, varscan2
- LRP12 | c.1154A>C p.N385T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV52626891; called by muse, mutect2, varscan2
- LRP1B | c.13295A>G p.K4432R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.98); catalogued as rs1295002871, COSV67250116; called by muse, mutect2
- MUC7 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 63/109 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as rs1250375543, COSV59217017; called by muse, mutect2, varscan2
- MYT1 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs761239924; called by muse, mutect2, varscan2
- NAGA | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs144560510; called by muse, mutect2, varscan2
- NLRP14 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55069677; called by muse, mutect2, varscan2
- NTRK1 | c.1125G>A p.M375I | Missense Mutation (SNP) | VAF 48/65 reads (74%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs770611182, COSV62327894; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR10J1 | c.779A>C p.K260T | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101419893, COSV101420054, COSV71128324; called by muse, mutect2, varscan2
- OR10J1 | c.920A>C p.K307T | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.703); catalogued as COSV71128377, COSV71128978; called by muse, mutect2, varscan2
- OR10R2 | c.866A>C p.N289T | Missense Mutation (SNP) | VAF 72/104 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV63768713; called by muse, mutect2, varscan2
- OR4C15 | c.379T>C p.S127P (on ENST00000314644; = p.S73P on NM_001001920.2) | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV58951546, COSV58952166; called by muse, mutect2, varscan2
- OR4D5 | c.401T>G p.L134R | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV100189789; called by muse, mutect2, varscan2
- OR51E2 | c.82T>G p.F28V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.261); catalogued as rs776445651; called by muse, mutect2, varscan2
- OR52N1 | c.133T>G p.F45V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.028); catalogued as COSV57692824; called by muse, varscan2
- OR52N1 | c.69A>C p.E23D | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100398647; called by muse, varscan2
- OR6K6 | c.1004A>G p.Q335R (on ENST00000368144; = p.Q311R on NM_001005184.1) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs559439148, COSV63744886; called by mutect2, varscan2
- OR8D2 | c.644T>G p.L215R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV100659003; called by muse, varscan2
- OR8D2 | c.614T>G p.V205G | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV62488572; called by muse, varscan2
- PCLO | c.11754A>C p.Q3918H | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.74); catalogued as COSV61615390, COSV61633767, COSV61640511; called by muse, mutect2, varscan2
- PCLO | c.4487A>C p.K1496T | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as COSV61639903; called by muse, mutect2
- PEG3 | c.4236A>C p.E1412D | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV55625532, COSV55636235; called by muse, varscan2
- PEG3 | c.4194A>T p.E1398D | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); catalogued as COSV99686961, COSV99689984; called by muse, varscan2
- PLG | c.2155G>T p.A719S | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as rs1003565868; called by muse, mutect2, varscan2
- PLPPR5 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as rs775194002; called by muse, mutect2, varscan2
- POU6F1 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.776); catalogued as rs754543222; called by muse, mutect2
- PXDNL | c.4207A>G p.R1403G | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs868605102; called by muse, mutect2, varscan2
- RET | c.1694G>T p.C565F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV60695447; called by mutect2, varscan2
- RFX5 | c.514A>G p.M172V | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.544); catalogued as rs767055616, COSV51837928; called by muse, mutect2, varscan2
- RFX6 | c.1044T>G p.N348K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.05); catalogued as COSV60585078; called by muse, mutect2, varscan2
- RYR3 | c.2776A>C p.T926P | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV66789887; called by muse, mutect2, varscan2
- SALL1 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.137); catalogued as rs554062425, COSV51752947, COSV51761027; called by muse, mutect2, varscan2
- SCN7A | c.628A>C p.T210P | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV101313404; called by muse, mutect2, varscan2
- SEH1L | c.190A>C p.T64P | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV50817372; called by muse, mutect2, varscan2
- SERPINB6 | c.827C>T p.T276M (on ENST00000612421 / NM_001271823.2; = p.T257M on NM_004568.6) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs758304446, COSV100177436; called by muse, mutect2, varscan2
- SETBP1 | c.4052A>C p.N1351T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as COSV56313990; called by muse, mutect2, varscan2
- SI | c.4846T>A p.F1616I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV104387974; called by muse, mutect2, varscan2
- SLC4A2 | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs146252856; called by muse, mutect2, varscan2
- SLC9A2 | c.1846A>T p.T616S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.292); catalogued as rs757389529; called by muse, mutect2, varscan2
- SNTG2 | c.1131A>C p.Q377H | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV57974395; called by muse, mutect2, varscan2
- SORCS3 | c.2771T>G p.V924G | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63794008; called by muse, mutect2, varscan2
- SYNE1 | c.10179T>G p.S3393R (on ENST00000367255 / NM_182961.4; = p.S3400R on NM_033071.3) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs973146421; called by muse, mutect2
- TECTA | c.4421A>C p.N1474T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV50707748; called by muse, mutect2, varscan2
- TFPI2 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV55990063; called by muse, mutect2, varscan2
- TIMD4 | c.38A>C p.E13A | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV99193004; called by muse, mutect2, varscan2
- TPTE | c.1486T>G p.F496V (on ENST00000618007 / NM_199261.4; = p.F478V on NM_199259.4) | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1443822256; called by muse, mutect2, varscan2
- TRIM49 | c.979A>C p.S327R | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV61670608; called by muse, mutect2
- TTN | c.10216G>C p.A3406P (on ENST00000591111; = p.A3360P on NM_003319.4) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | PolyPhen probably damaging (0.93); catalogued as COSV60178233; called by muse, mutect2, varscan2
- UBQLNL | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as rs777518193, COSV100974143; called by muse, mutect2, varscan2
- USH2A | c.5543A>C p.N1848T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as COSV100238326, COSV56399593; called by muse, mutect2, varscan2
- VIM | c.1169A>C p.K390T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99812849; called by muse, mutect2, varscan2
- VN1R4 | c.356T>G p.L119R | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100237332, COSV60804850; called by muse, mutect2, varscan2
- ZBED9 | c.2486C>T p.P829L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated, low confidence (0.72); PolyPhen probably damaging (0.995); catalogued as rs142639079; called by muse, mutect2, varscan2
- ZNF385B | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs530550928, COSV61178896; called by muse, mutect2, varscan2
- ZNF536 | c.3826T>A p.L1276I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.368); catalogued as COSV100836246, COSV62824365; called by muse, mutect2, varscan2
- ZNF568 | c.523T>G p.F175V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100451468; called by mutect2, varscan2
- ADAM32 | c.589A>C p.T197P | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- AJAP1 | c.812T>G p.I271S | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- AL592490.1 | c.791A>G p.E264G | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ANAPC4 | c.2405T>G p.L802R | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- APOB | c.8030A>C p.D2677A | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARL15 | c.398G>A p.C133Y | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ASTN2 | c.1689C>A p.Y563* (on ENST00000313400 / NM_001365069.1; = p.Y512* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- ATP10D | c.2977T>G p.L993V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.139); called by mutect2, varscan2
- AXIN2 | c.2193G>T p.Q731H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CACNA2D3 | c.2489A>C p.K830T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CFAP69 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- COL12A1 | c.7939A>C p.S2647R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- CPXM2 | c.1777A>C p.S593R | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- DCLK2 | c.1832A>G p.E611G | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DNAH5 | c.11837T>A p.L3946* | Nonsense Mutation (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- DNAH5 | c.10996A>G p.R3666G | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- DPYSL4 | c.1253A>C p.K418T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EVC | c.2810A>C p.K937T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FAM155A | c.87C>A p.F29L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- FGD4 | c.90C>T p.G30= | Splice Region (SNP) | VAF 16/25 reads (64%) | called by muse, mutect2, varscan2
- FGF13 | c.367T>G p.L123V | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FSHR | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- GATB | c.1333C>A p.P445T | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GNPTAB | c.718A>G p.T240A | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); called by muse, mutect2
- HTR2A | c.1018T>G p.F340V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1D-17 | c.115G>T p.D39Y | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- INAVA | c.1040+1G>T p.X347_splice | Splice Site (SNP) | VAF 27/44 reads (61%) | called by muse, mutect2, varscan2
- ITGA5 | c.949T>G p.F317V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF5C | c.661_662insC p.E221Afs*12 | Frame Shift Ins (INS) | VAF 19/62 reads (31%) | called by mutect2, varscan2
- LRRC31 | c.579G>T p.K193N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAGEE2 | c.746T>G p.F249C | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- MAP2 | c.4991A>C p.N1664T | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MRPL28 | c.467A>C p.K156T | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MSS51 | c.830T>G p.L277R | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.39); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- MUC16 | c.6104T>G p.L2035R | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MUC16 | c.5285T>G p.F1762C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- NAA11 | c.584A>C p.K195T | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- NAV3 | c.2488A>C p.S830R | Missense Mutation (SNP) | VAF 67/97 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- NKX2-5 | c.890T>A p.V297D | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NLRP5 | c.1876T>G p.F626V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NR2C2 | c.1175G>A p.R392H (on ENST00000393102; = p.R411H on NM_003298.5) | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2C3 | c.229A>G p.S77G | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- OR2M7 | c.584T>A p.F195Y | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- OR4C6 | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- OR51A7 | c.664A>T p.K222* | Nonsense Mutation (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- OR5H1 | c.128T>G p.L43R | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- OR8D2 | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- OR9G1 | c.595T>C p.Y199H | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- PCDHA13 | c.1673A>T p.E558V | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- PLCG1 | c.3314G>A p.R1105Q | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PLCXD3 | c.568C>G p.Q190E | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- PLEKHA6 | c.1963A>T p.I655F | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2
- POLE | c.169G>C p.G57R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRAMEF17 | c.599A>C p.K200T | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- PRAMEF20 | c.530T>C p.L177S | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PRAMEF20 | c.1023A>C p.Q341H | Missense Mutation (SNP) | VAF 81/238 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF17 | c.252A>C p.Q84H | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- RP1L1 | c.6204A>C p.E2068D | Missense Mutation (SNP) | VAF 26/738 reads (4%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.023); called by muse, mutect2
- SCAMP3 | c.615G>A p.W205* | Nonsense Mutation (SNP) | VAF 35/53 reads (66%) | called by muse, mutect2, varscan2
- SCIN | c.1285T>G p.Y429D (on ENST00000297029 / NM_001112706.3; = p.Y182D on NM_033128.3) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCN9A | c.4134A>C p.Q1378H (on ENST00000303354; = p.Q1367H on NM_002977.3) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SGCD | c.310A>C p.K104Q (on ENST00000435422 / NM_001128209.2; = p.K105Q on NM_000337.5) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC6A17 | c.1815+1G>A p.X605_splice | Splice Site (SNP) | VAF 20/32 reads (63%) | called by muse, mutect2, varscan2
- SLC6A19 | c.146_147insAAG p.C49delins* | Nonsense Mutation (INS) | VAF 49/119 reads (41%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.2040A>C p.Q680H | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- STK32B | c.977A>G p.H326R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- SYNE1 | c.24466A>C p.I8156L (on ENST00000367255 / NM_182961.4; = p.I8085L on NM_033071.3) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYNE1 | c.2952A>C p.E984D (on ENST00000367255 / NM_182961.4; = p.E991D on NM_033071.3) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- SYNE1 | c.422A>C p.N141T (on ENST00000367255 / NM_182961.4; = p.N148T on NM_033071.3) | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TESPA1 | c.942A>C p.Q314H (on ENST00000316577 / NM_001098815.3; = p.Q176H on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- TEX9 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
- TFEC | c.814A>G p.S272G | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- TMEM200A | c.1198T>G p.L400V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TTN | c.54708A>C p.K18236N (on ENST00000591111; = p.K10812N on NM_003319.4) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- TTN | c.52970A>C p.K17657T (on ENST00000591111; = p.K10233T on NM_003319.4) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- TTN | c.21812A>T p.Q7271L (on ENST00000591111; = p.Q6344L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | PolyPhen benign (0.001); called by muse, mutect2
- UNC13C | c.6010A>C p.S2004R | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WNK3 | c.4710A>T p.K1570N | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ZNF296 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- ZNF582 | c.380A>G p.Q127R | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.047); called by muse, mutect2
- ZNF667 | c.27A>C p.K9N | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.179); called by muse, mutect2
- ZNF680 | c.546C>G p.F182L | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- ZNF883 | c.368_369dup p.P124Nfs*46 | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- CBLN1 | c.195T>C p.S65= | Silent (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- CCDC178 | c.384T>C p.S128= | Silent (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- COL23A1 | c.666C>T p.D222= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs140937912, COSV66794290; called by muse, mutect2, varscan2
- CRCT1 | c.141C>T p.C47= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV100524189, COSV57500251; called by muse, mutect2, varscan2
- CRNKL1 | c.342T>G p.G114= | Silent (SNP) | VAF 20/124 reads (16%) | called by muse, mutect2, varscan2
- DCLK1 | c.2094A>G p.R698= (on ENST00000360631 / NM_001330072.2; = p.D723G on NM_004734.5) | Silent (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- FREM1 | c.804T>C p.D268= | Silent (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- FRMPD4 | c.1872T>C p.S624= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- GIMAP8 | c.1680G>A p.A560= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs1203845409, COSV56229956; called by muse, mutect2, varscan2
- GPRC6A | c.504T>G p.G168= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- HCN4 | c.1809C>T p.F603= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as rs747530859, COSV99983914; called by muse, mutect2, varscan2
- HECTD4 | c.10077C>A p.L3359= | Silent (SNP) | VAF 38/120 reads (32%) | called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.12T>G p.T4= | Silent (SNP) | VAF 32/106 reads (30%) | called by muse, mutect2, varscan2
- IL19 | c.381T>C p.C127= | Silent (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- INSYN2A | c.273C>T p.P91= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as rs374772780; called by muse, mutect2, varscan2
- KIF1B | c.3354T>A p.T1118= (on ENST00000377086 / NM_001365952.1; = p.T1072= on NM_015074.3) | Silent (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- MUC16 | c.28392T>G p.T9464= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as rs751502909; called by muse, mutect2, varscan2
- NNT | c.1914C>T p.L638= | Silent (SNP) | VAF 37/306 reads (12%) | called by muse, varscan2
- OPRK1 | c.318T>G p.A106= | Silent (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- OR2L8 | c.61A>C p.R21= | Silent (SNP) | VAF 37/164 reads (23%) | catalogued as COSV100594029, COSV100594290; called by muse, mutect2, varscan2
- OR2T4 | c.675A>G p.S225= | Silent (SNP) | VAF 19/181 reads (10%) | catalogued as COSV63544240; called by muse, mutect2, varscan2
- OR51I1 | c.942C>G p.A314= | Silent (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- OR5L1 | c.411T>G p.S137= | Silent (SNP) | VAF 28/98 reads (29%) | called by muse, mutect2, varscan2
- OR5T2 | c.681T>G p.S227= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as COSV57588476, COSV57589308, COSV57590451; called by muse, mutect2, varscan2
- PCDH19 | c.495T>G p.T165= | Silent (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- PCDHA3 | c.1812C>T p.N604= | Silent (SNP) | VAF 57/160 reads (36%) | called by muse, mutect2, varscan2
- PCDHB12 | c.993T>C p.S331= | Silent (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- PIKFYVE | c.5361C>T p.G1787= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs771148203; called by muse, mutect2
- PRAMEF15 | c.1044A>G p.E348= | Silent (SNP) | VAF 12/176 reads (7%) | called by muse, mutect2
- PREX2 | c.2838T>G p.S946= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as rs1361294223, COSV55789196; called by muse, mutect2, varscan2
- PTPRB | c.2514T>A p.T838= | Silent (SNP) | VAF 13/23 reads (57%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.2871T>G p.T957= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV66429410, COSV66438309; called by muse, mutect2, varscan2
- RALGAPB | c.366C>T p.H122= | Silent (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- RELN | c.1230T>C p.D410= | Silent (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- RIMS2 | c.1269T>G p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV51651026, COSV51655287, COSV51702036; called by muse, mutect2, varscan2
- RIMS2 | c.1794A>T p.G598= (on ENST00000666250 / NM_001348490.2; = p.G406= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV99156869; called by muse, mutect2, varscan2
- SCG3 | c.144A>G p.E48= | Silent (SNP) | VAF 26/46 reads (57%) | called by muse, mutect2, varscan2
- SEMA3F | c.981G>A p.P327= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs772034460, COSV50035871; called by muse, mutect2, varscan2
- SGCD | c.21T>A p.T7= (on ENST00000435422 / NM_001128209.2; = p.T8= on NM_000337.5) | Silent (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- SLC22A18 | c.36G>A p.R12= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs533027622; called by muse, mutect2, varscan2
- SLC25A26 | c.585A>C p.A195= | Silent (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- SLC30A8 | c.648T>C p.A216= | Silent (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- SYCP1 | c.39G>A p.P13= | Silent (SNP) | VAF 29/102 reads (28%) | called by muse, mutect2, varscan2
- TTPA | c.618C>A p.V206= | Silent (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- UHRF1BP1L | c.3051G>A p.S1017= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs759457606, COSV54435940; called by muse, mutect2, varscan2
- VAX1 | c.255C>A p.S85= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as COSV99524496; called by muse, mutect2, varscan2
- ZBTB16 | c.1539G>A p.A513= | Silent (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2
- AGAP7P | n.1278C>T | RNA (SNP) | VAF 28/205 reads (14%) | catalogued as rs782278610; called by muse, mutect2, varscan2
- GABRG2 | c.1249-635T>G | Intron (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- MIR892A | n.59T>C | RNA (SNP) | VAF 32/48 reads (67%) | catalogued as rs1569513481; called by muse, mutect2, varscan2
- NALCN | c.1765-4857T>G | Intron (SNP) | VAF 8/78 reads (10%) | catalogued as COSV51922869, COSV51925386, COSV51970703; called by muse, mutect2, varscan2
- OR3A4P | n.573C>A | RNA (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- TXNRD3 | n.634A>G | RNA (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- UGT3A2 | c.-2G>A | 5'UTR (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
